Surgical pathology report (de-identified scan), TCGA case TCGA-F7-A622, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-F7-A622-01A (Primary Tumor).

Gross Description: There is larynx with an ulcerated white-gray dense tumor. Separately there is a fragment of the thyroid gland up to 2 x 2 cm in size.

Microscopic Description: Squamous carcinoma, keratinizing type, G-1. Thyroid gland tissue is of the normal structure.

Diagnosis Details: Tumor Features: Ulcerated, Tumor Extent: Localized, NOS , Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments: Endoscopies, figrolaryngoscopy show cancer of the larynx with the involvement of all parts of the organ.

Formatted Path Reports: LARYNX TISSUE CHECKLIST

Specimen type: Laryngectomy

Tumor site: Larynx

Tumor size: 1 x 0 x 1.5 cm

Histologic type: Squamous cell carcinoma, keratinizing

Histologic grade: Well differentiated

Tumor extent: Not specified

Lymph nodes: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Comments: Tumor Features: Ulcerated, Tumor Extent: Localized, NOS , Venous Invasion: Absent, Margins: Absent, Endoscopies, figrolaryngoscopy show cancer of the larynx with the involvement of all parts of the organ.

ICD-3
Carcinoma, squamous cell,
Keratinizing NOS 8071/3
Site: Larynx, NOS C32.9
JW 4/12/13

HPV/A Discrepancy		☒
Reviewed/Initials:	Date Reviewed: 3/25/13	

Source: NCI Genomic Data Commons file f26ebfe1-3222-454b-87d8-c95a377b453b (TCGA-F7-A622.7FBCFE10-3C3C-4EF6-ACFA-DDF88D874AFD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).